Surgical pathology report (de-identified scan), TCGA case TCGA-N1-A6IA, project TCGA-SARC (Sarcoma), tissue source site Montefiore Medical Center, specimen TCGA-N1-A6IA-01A (Primary Tumor).

[page 1 of 6]
Patient Name:

Med Rec #:

Requested By:

Ordered By:

Report Name: :

ICD-3

Leiomyosarcoma NOS

8890/3

Site: Uterus NOS

8559

JW 6/18/13

Surg Path Case - STATUS: Final

**SEE NOTE

Collect/Perform:

Ordered By:

Ordered Date:

Facility:

Department:

Physician Who Performed Procedure:

Requesting Physician:

SURGICAL PATHOLOGY,

CASE#:

Attending Pathologist :

DIAGNOSIS:

1. Uterus, cervix and bilateral ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy:

- High grade sarcoma of uterus best classified as leiomyosarcoma and measuring 5cm in greatest dimension.
- Focus suspicious for lymphovascular invasion
- Uterine leiomyoma.
- Proliferative endometrium with endometritis
- Acute and chronic cervicitis.
- RIGHT ovary with hemorrhagic corpus luteum cyst.
- RIGHT fallopian tube with paratubal cysts.
- LEFT ovary and fallopian tube with no significant histopathologic findings.
- See synoptic report below.

2. Lymph node, LEFT pelvis, biopsy:

- Six (6) lymph nodes, negative for tumor (0/6).

3. Lymph node, RIGHT pelvis, biopsy:

- Fibroadipose tissue with extensive acute inflammation and cautery artifact.
- No lymph node identified.

4. Omentum, biopsy:

- Fibroadipose tissue with extensive acute inflammation and reactive

Page 1

[page 2 of 6]
Patient Name:

Med Rec #:

Requested By:

Ordered By:

Report Name: :

fibrosis.

FULL SYNOPTIC REPORT

- Histologic Type: High grade sarcoma consistent with Uterine leiomyosarcoma
- Histologic Grade: G3 - poorly differentiated
- Tumor Size:
- Greatest dimension: 5.0cm; other two dimensions: 4.0 x 2.5cm
- Specimen Integrity: Intact
- Tumor Site: Anterior and posterior
- Myometrial Invasion: Present - 92%
- Depth of invasion: 2.4cm - more than 50% myometrial invasion
- Myometrial thickness: 2.6cm
- Cervical Stromal Invasion: Absent
- Lymph-vascular Invasion: suspicious focus
- Paracervical Soft Tissue Margin: Indeterminate
- Other Tissues/Organs Involved: Bilateral ovaries, fallopian tubes and omentum negative for tumor
- Peritoneal Ascitic Fluid (from cytology report): Negative -
- Regional Lymph Node Metastasis:
- Pelvic nodes (number of positive/number examined): 0/6
- Para-aortic nodes (number of positive/number examined): Cannot be assessed
- Distant Metastasis (including abdominal lymph nodes): Cannot be determined
- Additional Pathologic Findings: Uterine leiomyoma, hemorrhagic corpus luteum cyst of RIGHT ovary, paratubal cyst of RIGHT fallopian tube; acute and chronic cervicitis
- Ancillary Studies:
- ER (immunohistochemical stain): pending
- PR (immunohistochemical stain):
- Other:
- AJCC Pathologic Staging: pT1a N0 MN/A; FIGO:

COMMENT: Slides reviewed with a second pathologist who concurs. Multiple immunostains are performed which do show some positive staining although very patchy for muscle markers caldesmin, desmin and SMA. Other positive markers include P16 and CD10. Cytokeratin shows patchy positivity. Given the fascicular/spindle morphology of the tumor coupled with atleast focal evidence of muscle differentiation by immunostaining we believe this is best classified as leiomyosarcoma.

[page 3 of 6]
Patient Name:

Med Rec #:

Requested By:

Ordered By:

Report Name:

.

.
CLINICAL INFORMATION:

Pelvic mass uterine cancer. Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, lymph node dissection, extensive lysis of adhesion, omentectomy.

CLINICAL INFORMATION:
.
GROSS DESCRIPTION:

1. The specimen is received fresh for intraoperative consultation and labeled uterus, cervix, tubes and ovaries. It consists of a 589 g, markedly distorted hysterectomy specimen with attached bilateral adnexa. The uterus measures 15.5cm from fundus to ectocervix, 10.0cm from cornu to cornu, and 8.5cm from anterior to posterior. The cervix is surfaced by a 2.5 x 2.2cm portion of tan-white glistening mucosa. The cervix exhibits a 0.5cm slitlike, probe patent os. The uterine serosa is tan-pink to red purple, smooth and glistening to focally shaggy. The anterior aspect of the serosa is inked in blue and the posterior aspect inked in black. The uterus is bivalved into anterior and posterior halves to reveal a 5.0 x 4.0 x 2.5cm tan-gray to tan-brown, exophytic mass identified in the endometrial cavity. The mass is located in the anterior and posterior fundus and focally extends to within 6.5cm of the cervical os, on the posterior aspect. The mass is located predominately in the fundic aspect of the endometrial cavity; however the mass approaches the posterior lower uterine segment. Cut section of the mass reveals a variegated, tan-gray to red-brown, soft cut surface. The mass extends into the myometrium, predominantly in the posterior fundus. The mass focally extends to within 0.2cm of the posterior uterine serosa. The tumor is diffusely softened with areas of apparent necrosis. The remainder of the endometrial cavity, which measures 8.0cm in length and 4.0cm across, exhibits tan-red, glistening endometrium, averaging 0.2cm in thickness. The myometrium is tan-pink and trabecular, ranging from 1.0cm up to 3.5cm in thickness. Also identified in the anterior fundus is a 1.0cm in greatest dimension ovoid, tan-white, rubbery intramural nodule. The nodule exhibits a tan-white to tan-yellow whorled, rubbery cut surface. The endocervical canal is tan-white, trabeculated and measures 2.5cm in length. The attached right ovary is tan-yellow, bosselated and measures 3.0 x 2.5 x 1.5cm. The ovary is sectioned to reveal a 1.3cm hemorrhagic, corpus luteum and several tan-white, corpora albicantia ranging up to 0.5 cm. The remainder of the cut surface consists of tan-pink ovarian stroma. The attached right fallopian tube is difficult to identify grossly, however adjacent to the right ovary is a 3.0 x 0.8cm red- purple tubular structure. The structure exhibits an apparent lumen on

[page 4 of 6]
Patient Name:

Med Rec #:

Requested By:

Ordered By:

Report Name: :

cut section. The attached left ovary is tan-yellow and bosselated and measures 2.0 x 1.5 x 1.2cm. The ovary is sectioned to reveal several tan-white corpora albicantia, ranging up to 0.3cm in greatest dimension. The remainder of the cut surface consists of tan-pink ovarian stroma. The attached left fallopian tube measures 4.0cm in length, ranges from 0.5cm up to 0.8cm in diameter and exhibits a fimbriated end. The tube exhibits a smooth glistening serosa and a pinpoint lumen on cut section. Representative sections of the aforementioned mass are submitted for frozen section. Additional representative sections are submitted for permanent section.

Cassette summary:

Note: Orange ink indicates bisected continuous section

1AFSC-1BFSC-frozen section residue

1C-1D-full-thickness tumor with deepest invasion, posterior

1E-1F-full-thickness tumor with deepest invasion, posterior

1G-1H-full thickness tumor to posterior lower uterine segment

1I-1J-full thickness tumor, anterior fundus to uninvolved endometrium

1K-1M-additional representative tumor, apparent necrotic areas

1N-anterior endomyometrium, full thickness

1O- full thickness, posterior endomyometrium

1P-intramural nodule

1Q-anterior cervix

1R-posterior cervix

1S-right ovary and right fallopian tube

1T-left ovary and left fallopian tube

Additional representative sections of tumor submitted in cassettes 1U-1X.

Additional representative sections of left fallopian tube submitted as total in cassettes

INTRAOPERATIVE CONSULTATION: High grade malignant spindle cell lesion.

Sections also reviewed by

Reported to

2. The specimen is received fresh and labeled left pelvic lymph node. It consists of a 6.0cm aggregate of tan-yellow fatty tissue within which multiple, irregular lymph nodes are identified, ranging from 0.4cm up to 2.5cm in greatest dimension. The larger lymph nodes are bisected to reveal cut surfaces ranging from tan-red to tan-yellow. The specimen is entirely submitted.

[page 5 of 6]
Patient Name:!

Med Rec #:

Requested By:

Ordered By:

Report Name:

Cassette summary:

2A-2C-each cassette contains one bisected lymph node

2D-two whole lymph nodes

2E-2M-remaining fatty tissue

3. The specimen is received fresh and labeled right pelvic lymph node. It consists of a 6.0cm aggregate of tan-yellow fatty tissue within which no discrete lymph nodes are grossly identified. Identified within the fatty tissues are portions of tan-pink vasculature surrounded by possible lymphoid tissue. The specimen is entirely submitted in cassettes 3A-3L.

4. The specimen is received fresh and labeled omentum. It consists of a 21.0 x 8.0 x 0.7cm irregular portion of tan-yellow omentum. The omentum is serially sectioned to reveal focally hemorrhagic, tan yellow lobulated fat. No discrete lesions or lymph nodes are grossly identified. Representative sections are submitted in cassettes 4A-4D.

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

2xCD10, 2xCALDESMON, 1xP16, 1xP53, 1xMYOGENIN, 2xMYOD-1, 1xVIMENTIN, 1xDESMIN, 1xEPIHELIAL MEMBRANE AG, 1xAE1:3, 1xSMOOTH MUSC ACTIN (SMA), 1xESTROGEN RECEPTOR, 1xPROGESTERONE RECEPTOR

** Electronic Signature **

**Electronically Signed Out by

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the final diagnosis(es).

Note: The histology, immunochemistry and in situ hybridization components for this case were performed at

The Attending Pathologist reviewed this case and made the diagnosis.

Where applicable, immunohistochemistry and in situ hybridization tests were developed and the performance characteristics determined by the

These tests have not been cleared or approved by the US Food and Drug Administration and the results should be correlated with other clinical and laboratory

Page 5

[page 6 of 6]
Patient Name:

Med Rec #:

Requested By:

Ordered By:

Report Name:

data. Appropriate controls were performed for all immunohistochemistry, in situ hybridization and histochemical tests.

Page 6

Source: NCI Genomic Data Commons file ff226ea9-edb4-4c05-9546-130544e92d26 (TCGA-N1-A6IA.2ABEDEC3-EBA4-4535-8C32-4027A6542CA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).